Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A39N, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A39N-01A (Primary Tumor).

SPECIMEN TAKEN:

TOTAL THYROID:

SPECIMEN TYPE: Total thyroidectomy

TUMOR SITE: Right lobe

HISTOLOGIC TYPE: Papillary carcinoma

TUMOR SIZE: Greatest dimension: 5.0 cm

FOCALITY: Unifocal

LYMPH NODES: None submitted

EXTENT OF INVASION

PRIMARY TUMOR:

pT3: Tumor >4cm, limited to thyroid

REGIONAL LYMPH NODES:

pNX: Cannot be assessed

DISTANT METASTASIS:

pMX: Cannot be assessed

MARGINS: Margins are uninvolved

Distance of invasive carcinoma from nearest margin: 1 mm (thyroid capsular margin)

VENOUS/LYMPHATIC INVASION: Present

ADDITIONAL PATHOLOGIC FINDINGS:

None identified

Note: There is a focus of necrosis within the tumor. Dr.

has reviewed

representative sections of this case and concurs. This case

was presented at the

ICD-0-3
carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9
AS
9/14/11

Source: NCI Genomic Data Commons file 3f72d667-ef0c-440b-8f3f-3768aa8b1681 (TCGA-ET-A39N.005A9931-5051-4739-AA85-86238410CEC4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).